Somatic mutation profile of tumor specimen ALCH-ACGT-TTR1-A (aliquot ALCH-ACGT-TTR1-A-12-0-D-A587-36) from ALCHEMIST case ALCH-ACGT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.0 years (21,919 days).
Specimen ALCH-ACGT-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac888f80-c68f-400c-afd8-73d8eef52bff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ACGT-NB1-A (Blood Derived Normal), aliquot ALCH-ACGT-NB1-A-1-0-D-A49Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/544d128e-1c4f-4766-bc74-48d6601b1caa

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAB11FIP5 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 36/704 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV50252808; called by muse, mutect2
- REST | c.773T>A p.V258E | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as CD1513323; called by muse, mutect2
- RGSL1 | c.1772T>C p.I591T | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs1275147995; called by muse, mutect2
- WDFY4 | c.6554G>T p.R2185L | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99629132; called by muse, mutect2
- ADGRL3 | c.796del p.T266Qfs*15 (on ENST00000506720 / NM_001322402.2; = p.T198Qfs*15 on NM_015236.6) | Frame Shift Del (DEL) | VAF 19/149 reads (13%) | called by mutect2, pindel, varscan2
- ARSB | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 70/1086 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- FANCA | c.473A>G p.H158R | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- FOXO4 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAA | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 32/753 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- QTRT2 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- RAB11FIP5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 36/708 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.145); called by muse, mutect2
- REXO1 | c.1536G>T p.K512N | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2
- RLF | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 38/1075 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.084); called by muse, mutect2
- SLC22A6 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2
- TTC28 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); called by muse, mutect2
- TTLL4 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2
- AGAP2 | c.1521C>T p.G507= (on ENST00000547588 / NM_001122772.2; = p.G171= on NM_014770.4) | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- PRG4 | c.2742A>T p.T914= | Silent (SNP) | VAF 50/710 reads (7%) | called by muse, mutect2
- STKLD1 | c.576G>A p.A192= | Silent (SNP) | VAF 31/418 reads (7%) | catalogued as rs782653973, COSV64312648; called by muse, mutect2
- TEKT4 | c.444G>A p.E148= | Silent (SNP) | VAF 26/375 reads (7%) | called by muse, mutect2
- VPS26C | chr21:37221261 G>T | 3'Flank (SNP) | VAF 34/594 reads (6%) | called by muse, mutect2
